Surgical pathology report (de-identified scan), TCGA case TCGA-IB-7652, project TCGA-PAAD (Pancreatic Adenocarcinoma), tissue source site Alberta Health Services, specimen TCGA-IB-7652-01A (Primary Tumor).

[page 1 of 4]
Surgical Pathology Report

Inquiry Numbers

Accession Number:

Collected Date:

Pathologist:

Received Date/Time:

Specimen Description

- A. Neck, body and tail of pancreas
- B. Spleen
- C. Pedunculated mass of posterior wall

Clinical Information

Lesion in tail of pancreas, aspirate from EUA indicates ductal adenocarcinoma.

Diagnosis

A. Neck, Body and Tail of Pancreas, Surgical Resection:

- Moderately differentiated infiltrating pancreatic ductal adenocarcinoma.
- maximum diameter 4.2 cm, extending into peripancreatic fat and focally to the retroperitoneal margin
- Metastatic carcinoma in one of twenty peripancreatic lymph nodes (1/20)

B. Spleen, Splenectomy:

- No pathologic abnormalities.

C. Pedunculated Mass of Posterior Wall (Stomach), Surgical Resection:

[page 2 of 4]
Inquiry Number

Surgical Pathology Report

Accession Number:

Collected Date:

Pathologist:

Received Date/Time:

- **Benign calcifying fibrous tumor**

Reported by:

Synoptic Report

A: Pancreas (Exocrine), Microscopic

HISTOLOGIC TYPE:

Ductal adenocarcinoma

HISTOLOGIC GRADE:

G2: Moderately differentiated

MICROSCOPIC TUMOR EXTENSION:

Tumor invades peripancreatic soft tissues

MARGINS:

Margin(s) involved by invasive carcinoma

Invasive carcinoma involves posterior retroperitoneal surface of pancreas

TREATMENT EFFECT (applicable to carcinomas treated with neoadjuvant therapy):

Not known

LYMPH-VASCULAR INVASION:

Not identified

PERINEURAL INVASION:

Present

PRIMARY TUMOR (pT):

pT3: Tumor extends beyond the pancreas but without involvement of the celiac axis or the superior mesenteric artery

REGIONAL LYMPH NODES (pN):

pN1: Regional lymph node metastasis

Number examined: 20

Number involved: 1

[page 3 of 4]
Inquiry Number:

Surgical Pathology Report

Accession Number:

Collected Date:

Pathologist:

Received Date/Time:

Gross Description

Received are specimens A to C. All requisitions and specimen containers are labelled with the patient's name. The cassettes and AP identifiers are labelled with the Surgical Number.

A. Devitalization time is [REDACTED]. The specimen weighs 54.8 g and measures 9.5 x 4.8 x 2.3 cm. The surface shows an unremarkable proximal resection margin, painted orange. The posterior resection margin has been painted blue. No orientation marks are identified. The cut surface shows an irregularly ovoid mass measuring 4.2 cm transversely, 2.9 cm vertically and 2.1 cm from anterior to posterior. This mass is located at 1.9, 0.3, 4.5, 0.2, 0.1 and 0.2 cm from the proximal, superior, distal, inferior, anterior and posterior margins respectively. This mass is firm with yellow and white nodular areas and is surrounding the middle portion of the splenic blood vessels. Representative sections are submitted as follows:

- A1 - proximal resection margin en face.
- A2 - distal resection margin en face.
- A3 - whole section of tumor including superior, anterior, inferior and posterior margins.
- A4 - upper area of the tumor, blood vessels and a lymph node.
- A5-6 - full section showing a cystic area.
- A7-8 - full section showing a second lymph node.
- A9-10 - additional section of tumor.
- A11 - potential lymph nodes at the tail of the pancreas.
- A12 - potential lymph node inferior area of the pancreas.
- A13 - potential nodes superior edge of pancreas.

B. Devitalization time [REDACTED]. The specimen weighs 338.8 g and measures 12 x 7.5 x 4.9 cm. The surface shows an unremarkable wrinkled capsule. The cut surface shows unremarkable white and red pulp. No nodular or indurated areas are identified. Representative sections are submitted as follows:

- B1-3 - random sections of unremarkable splenic tissue.
- B4 - potential lymph nodes bisected, two in one cassette.
- B5-6 - further potential lymph nodes.

C. Devitalization time [REDACTED]. An ovoid fragment of soft tissue measuring 1.3 x 1 x 0.9 cm. The surface is smooth and one 0.6 x 0.3 cm stalk is identified and painted blue. The specimen is transected and submitted in cassette C1.

Microscopic Description

The slides show a malignant proliferation of epithelial cells showing primitive glandular formations in more than 50% of the tumor. The mitotic index is 2/10HPF. The tumoral cells extend into the peripancreatic fatty tissue with perineural invasion. Some of the tumoral cells extend into the muscular layer of large blood vessels but no lymph/vascular space

Cc:

[page 4 of 4]
Inquiry Number

Surgical Pathology Report

Accession Number:

Collected Date:

Pathologist:

Received Date/Time:

Invasion is identified. In some fields the tumoral glands are located at less than 0.1 cm from the inked resection margin, with desmoplastic stroma extending to the inked retroperitoneal margin.

The nodule on the posterior wall of stomach shows encapsulated paucicellular fibrous tumor with prominent calcification in the form of small psammoma-like structures, larger dystrophic calcifications, and focal linear calcium deposition along capillaries. No cytologic atypia is present. Stains for S100, Actin and SMMS are negative. CD117 is negative in the sparse spindled cells, but highlights background mast cells.

Source: NCI Genomic Data Commons file 4d797c34-a99b-453c-a7ff-f727556d9072 (TCGA-IB-7652.9533F051-C038-415D-952E-20314D097E13.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).